Gene-level copy-number profile of tumor specimen TCGA-3N-A9WB-06A from TCGA case TCGA-3N-A9WB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-3N-A9WB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.27b48eb1-52a9-456e-b5fa-6fc7414f62dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3N-A9WB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6d97eefd-58ba-4b88-b656-05169558f6b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 5,019; copy number 2: 43,745; copy number 3: 6,974; copy number 4: 2,384; copy number 5: 791; copy number 7: 373; copy number 8: 111; copy number 9: 107; copy number 13: 173; copy number 16: 116.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3N-A9WB-06A-11D-A38F-01): tumor purity 0.91, ploidy 2.24, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes (within-gene range 0–1): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,671 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:107,056,674–121,580,524, 373 genes, copy number 7 (broad region; genes not listed).
- chr1:236,664,141–247,880,138, 219 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–62,275,678, 1,079 genes, copy number 5–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,632. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
